Gene-level copy-number profile of tumor specimen TCGA-21-1072-01A from TCGA case TCGA-21-1072, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.0 years (27,397 days).
Specimen TCGA-21-1072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.799b0ce4-2414-4033-a832-1ca813645e51.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-1072-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62523d46-0b9f-4cfe-b655-e5a9d74eb94f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 26,438; copy number 2: 30,634; copy number 3: 1,418; copy number 4: 1,089; copy number 5: 190.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-21-1072-01): tumor purity 0.74, ploidy 3.38, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:127,968,785–128,520,616, 1 gene (within-gene range 0–1): PTPRK.
- chr6:128,500,527–128,761,808, 5 genes: AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA.
- chr10:48,684,876–48,982,956, 1 gene (within-gene range 0–1): WDFY4.
- chr10:48,835,541–49,396,016, 14 genes: AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4, FAM170B-AS1, FAM170B, TMEM273, C10orf71-AS1, C10orf71, DRGX.
- chr22:50,529,710–50,801,309, 22 genes: ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 190 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:64,442,510–74,728,851, 190 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,333. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
